Somatic mutation profile of tumor specimen TCGA-B6-A0RP-01A (aliquot TCGA-B6-A0RP-01A-21D-A099-09) from TCGA case TCGA-B6-A0RP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 73.8 years (26,941 days).
Specimen TCGA-B6-A0RP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b03aa35-7a3b-4acd-9b1f-248222075a4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RP-10A (Blood Derived Normal), aliquot TCGA-B6-A0RP-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccd7bb92-15f5-4e04-9b60-7ea91e0c3db7

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 27/41 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, varscan2
- TPSD1 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 24/93 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as rs3865205, COSV52973780; called by muse, varscan2
- ACOX3 | c.829A>T p.M277L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV62711638; called by muse, mutect2, varscan2
- CASP8 | c.745G>T p.E249* (on ENST00000432109 / NM_033355.3; = p.E266* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as COSV51857499; called by muse, mutect2, varscan2
- CES1 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV62089529; called by muse, mutect2, varscan2
- DOCK8 | c.2428G>T p.A810S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV66623078, COSV66623942; called by muse, varscan2
- FREM2 | c.7579C>T p.R2527C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs963299361, COSV54848659, COSV99747301; called by muse, mutect2, varscan2
- GALNTL5 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs200879913; called by muse, mutect2, varscan2
- HDAC1 | c.50-2A>G p.X17_splice | Splice Site (SNP) | VAF 19/47 reads (40%) | catalogued as COSV65191955; called by muse, mutect2, varscan2
- HYAL2 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781930973, COSV100753910, COSV63306026; called by muse, mutect2
- KMT2C | c.13273G>T p.D4425Y | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51487965, COSV51502540; called by muse, mutect2, varscan2
- MAGEB6B | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1328305476; called by muse, mutect2
- MROH7 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1212046975, COSV59876535; called by muse, mutect2, varscan2
- MUC16 | c.30931G>A p.G10311S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV67486815; called by muse, mutect2, varscan2
- PIP4K2C | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV61606839; called by muse, mutect2, varscan2
- SRCIN1 | c.816C>G p.N272K (on ENST00000621492; = p.N238K on NM_025248.3) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs868705738; called by muse, mutect2, varscan2
- THAP12 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52609428; called by muse, mutect2, varscan2
- TNNI3 | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV61279010; called by muse, mutect2, varscan2
- TTN | c.70399C>T p.P23467S (on ENST00000591111; = p.P16043S on NM_003319.4) | Missense Mutation (SNP) | VAF 14/125 reads (11%) | PolyPhen probably damaging (0.998); catalogued as COSV60278996; called by muse, mutect2, varscan2
- ZFC3H1 | c.5507A>T p.N1836I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV66435314; called by muse, mutect2, varscan2
- COL6A5 | c.6480G>A p.S2160= (on ENST00000312481; = p.S2156= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/98 reads (63%) | catalogued as rs778454018, COSV55193358, COSV99592791; called by muse, mutect2, varscan2
- KCND1 | c.1224G>A p.V408= | Silent (SNP) | VAF 58/113 reads (51%) | catalogued as COSV54415557; called by muse, mutect2, varscan2
- POLD2 | c.915G>A p.T305= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as rs145093588; called by muse, mutect2, varscan2
- SHOC1 | c.648A>G p.E216= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs770935811, COSV59506210; called by muse, mutect2, varscan2
